Somatic mutation profile of tumor specimen ALCH-B3E3-TTP1-A (aliquot ALCH-B3E3-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B3E3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.2 years (22,725 days).
Specimen ALCH-B3E3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0824f2c-36ac-4f73-a663-c7d156cf1e14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3E3-NB1-A (Blood Derived Normal), aliquot ALCH-B3E3-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fca3c679-c4c2-44ed-a821-47228ab4eb29

The open-access MAF lists 330 somatic variants for this specimen: 229 protein-altering or splice-affecting, 63 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 204, Silent 63, Intron 18, Nonsense Mutation 11, 5'UTR 8, 3'UTR 6, Splice Site 6, Splice Region 5, RNA 3, 5'Flank 3, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 57/667 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- TP53 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 18/226 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730882000, COSV52661847, COSV52680639, COSV52688008, COSV52782769; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- AFM | c.1391T>C p.L464P | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1305597859, COSV56919777; called by muse, mutect2
- AKAP12 | c.3787G>A p.G1263R | Missense Mutation (SNP) | VAF 24/471 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs1562755673; called by muse, mutect2
- AKR1E2 | c.568C>G p.P190A | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53631699; called by muse, mutect2
- AMER3 | c.1138G>T p.V380L | Missense Mutation (SNP) | VAF 28/434 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV58469562; called by muse, mutect2
- APOA2 | c.93G>C p.E31D | Missense Mutation (SNP) | VAF 23/592 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as rs1346496201; called by muse, mutect2
- ARHGEF12 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 34/425 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as COSV63103099; called by muse, mutect2
- ARHGEF33 | c.2464C>T p.R822C | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1429106675; called by muse, mutect2
- ATP8B3 | c.2078G>T p.R693L | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs547170926, COSV59549762; called by muse, mutect2
- C16orf96 | c.3253C>A p.H1085N | Missense Mutation (SNP) | VAF 26/461 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as rs1370732681; called by muse, mutect2
- CACNA1C | c.1931T>A p.L644* | Nonsense Mutation (SNP) | VAF 9/107 reads (8%) | catalogued as rs786205749; called by muse, mutect2
- CDH15 | c.838C>G p.R280G | Missense Mutation (SNP) | VAF 37/383 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99228044; called by muse, mutect2
- CLMN | c.2035C>T p.L679F | Missense Mutation (SNP) | VAF 30/506 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1341395995; called by muse, mutect2
- CSMD3 | c.7885G>T p.A2629S (on ENST00000297405 / NM_001363185.1; = p.A2525S on NM_052900.3) | Missense Mutation (SNP) | VAF 12/263 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV52252337; called by muse, mutect2
- CYP2C18 | c.356G>C p.R119T | Missense Mutation (SNP) | VAF 32/453 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0.031); catalogued as COSV99608514; called by muse, mutect2
- CYSLTR1 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV100964753; called by muse, mutect2, varscan2
- DLG5 | c.5068C>T p.R1690W | Missense Mutation (SNP) | VAF 39/330 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748404592; called by muse, mutect2, varscan2
- DMBT1 | c.1781C>G p.S594* | Nonsense Mutation (SNP) | VAF 26/330 reads (8%) | catalogued as COSV57537894; called by muse, mutect2
- DMXL1 | c.7624G>T p.E2542* | Nonsense Mutation (SNP) | VAF 77/962 reads (8%) | catalogued as COSV100224673; called by muse, mutect2
- DNAH5 | c.6444+1G>T p.X2148_splice | Splice Site (SNP) | VAF 28/434 reads (6%) | catalogued as rs781236248; called by muse, mutect2
- ECPAS | c.2113G>T p.E705* | Nonsense Mutation (SNP) | VAF 35/443 reads (8%) | catalogued as COSV99399627; called by muse, mutect2
- EPB41L3 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 19/454 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59453719; called by muse, mutect2
- EPHA7 | c.1325-1G>T p.X442_splice | Splice Site (SNP) | VAF 24/395 reads (6%) | catalogued as COSV65181850; called by muse, mutect2
- EXOC3 | c.1859C>T p.P620L | Missense Mutation (SNP) | VAF 22/355 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs758540524; called by muse, mutect2
- F13B | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 26/481 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs559428305, COSV66373164; called by muse, mutect2
- FAT3 | c.6790C>A p.L2264I | Missense Mutation (SNP) | VAF 26/283 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV53142415; called by muse, mutect2
- GBE1 | c.14T>C p.M5T | Missense Mutation (SNP) | VAF 27/439 reads (6%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as rs1359193851; called by muse, mutect2
- GCSAML | c.64G>C p.G22R | Missense Mutation (SNP) | VAF 32/494 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100825910; called by muse, mutect2
- GP2 | c.386G>C p.G129A | Missense Mutation (SNP) | VAF 26/490 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs761068167; called by muse, mutect2
- GPC5 | c.1378G>T p.D460Y | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65603899; called by muse, mutect2
- HBE1 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.101); catalogued as rs374123155; called by muse, mutect2
- HSPA12B | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 26/489 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as COSV53923967; called by muse, mutect2
- IRX4 | c.595C>A p.R199S | Missense Mutation (SNP) | VAF 31/514 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51475485; called by muse, mutect2
- ISLR2 | c.2014G>T p.V672L | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV62301536; called by muse, mutect2
- ITGA6 | c.2029C>G p.L677V (on ENST00000442250; = p.L638V on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/714 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.175); catalogued as COSV51220459; called by muse, mutect2
- ITGA6 | c.2255A>G p.Y752C (on ENST00000442250; = p.Y713C on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/742 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.923); catalogued as rs776579078; called by muse, mutect2
- KCNT2 | c.2940G>T p.W980C | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54072816, COSV54088810; called by muse, mutect2
- KLHL33 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1310208758; called by muse, mutect2
- LMTK3 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.199); catalogued as rs1396928085; called by muse, mutect2, varscan2
- LPA | c.4884C>A p.F1628L | Missense Mutation (SNP) | VAF 72/1068 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV60300085; called by muse, mutect2
- LRP1B | c.4979C>G p.S1660* | Nonsense Mutation (SNP) | VAF 14/244 reads (6%) | catalogued as COSV99081266; called by muse, mutect2
- LRRC3C | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 48/548 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as rs911786546; called by muse, mutect2
- MATN2 | c.2170C>A p.H724N | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.122); catalogued as COSV99646737; called by muse, mutect2
- MKRN3 | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 20/472 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.081); catalogued as COSV58811812; called by muse, mutect2
- NDUFA11 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 16/237 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs544224039, COSV53135991, COSV99398774; called by muse, mutect2
- NLRC4 | c.1540C>T p.Q514* | Nonsense Mutation (SNP) | VAF 13/209 reads (6%) | catalogued as COSV100707482, COSV61591349; called by muse, mutect2
- NLRP3 | c.2154G>C p.L718F | Missense Mutation (SNP) | VAF 45/703 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.231); catalogued as COSV100276182; called by muse, mutect2
- OR10K1 | c.534C>A p.F178L | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99193878; called by muse, mutect2
- OR4A47 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 30/578 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV71445161; called by muse, mutect2
- OR4C15 | c.794C>A p.S265Y (on ENST00000314644; = p.S211Y on NM_001001920.2) | Missense Mutation (SNP) | VAF 40/664 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.578); catalogued as COSV58951070, COSV58953111; called by muse, mutect2
- OR4P4 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV58923526; called by muse, mutect2, varscan2
- OR6P1 | c.608C>A p.A203D | Missense Mutation (SNP) | VAF 34/544 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104402220; called by muse, mutect2
- OR6Q1 | c.376C>G p.R126G | Missense Mutation (SNP) | VAF 19/282 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56933080; called by muse, mutect2
- OR8J3 | c.539A>T p.D180V | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56884277; called by muse, mutect2
- PAX4 | c.496C>A p.H166N | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.549); catalogued as rs1381461436; called by muse, mutect2
- PLD5 | c.748G>A p.G250S (on ENST00000442594; = p.G188S on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/247 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs775026704, COSV100138266, COSV59155144; called by muse, mutect2
- PNLIP | c.1391C>A p.P464Q | Missense Mutation (SNP) | VAF 22/518 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1161487380, COSV65041375; called by muse, mutect2
- PTPRZ1 | c.3215C>A p.P1072H | Missense Mutation (SNP) | VAF 21/377 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV66429728, COSV66435696; called by muse, mutect2
- SDK2 | c.3020G>T p.R1007L | Missense Mutation (SNP) | VAF 31/484 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV66187372; called by muse, mutect2
- SESN1 | c.946G>T p.D316Y (on ENST00000356644 / NM_001199933.1; = p.D375Y on NM_014454.3) | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100122800; called by muse, mutect2
- SLC35C2 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as COSV54756884; called by muse, mutect2
- SPTA1 | c.5108C>A p.A1703D | Missense Mutation (SNP) | VAF 47/1094 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as COSV63752396; called by muse, mutect2
- SRCAP | c.7970C>T p.S2657L | Missense Mutation (SNP) | VAF 36/602 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.023); catalogued as COSV99349893; called by muse, mutect2
- STYXL2 | c.457G>C p.G153R | Missense Mutation (SNP) | VAF 21/430 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV99068460; called by muse, mutect2
- TCF25 | c.548+6G>T | Splice Region (SNP) | VAF 104/754 reads (14%) | catalogued as rs1295585867; called by muse, mutect2, varscan2
- TCP11L2 | c.1527G>T p.M509I | Missense Mutation (SNP) | VAF 6/133 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV54429449; called by muse, mutect2
- TENT5D | c.733C>G p.H245D | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV57639401; called by muse, mutect2, varscan2
- TOMM40L | c.184-3C>T | Splice Region (SNP) | VAF 13/246 reads (5%) | catalogued as rs1267136532; called by muse, mutect2
- TPO | c.2477C>A p.A826E | Missense Mutation (SNP) | VAF 33/534 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV61095654; called by muse, mutect2
- TRPV6 | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 43/664 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs762853572, COSV63892983; called by muse, mutect2
- TSC22D4 | c.25A>G p.S9G | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as rs760982682; called by muse, mutect2, varscan2
- VWA1 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100100592; called by muse, mutect2
- WDR6 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 42/517 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.081); catalogued as rs780353651, COSV58244386; called by muse, mutect2
- ZFC3H1 | c.3538G>A p.E1180K | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); catalogued as COSV104430219; called by muse, mutect2
- ZIC4 | c.768C>A p.H256Q | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV67171515; called by muse, mutect2, varscan2
- ZNF513 | c.685G>C p.A229P | Missense Mutation (SNP) | VAF 26/321 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.157); catalogued as rs779353288; called by muse, mutect2
- ABCA12 | c.884T>C p.V295A | Missense Mutation (SNP) | VAF 54/917 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2
- ABCC11 | c.2404+1G>A p.X802_splice | Splice Site (SNP) | VAF 36/286 reads (13%) | called by muse, mutect2, varscan2
- ACOD1 | c.1327A>G p.K443E | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ADGRB1 | c.2893C>G p.L965V | Missense Mutation (SNP) | VAF 35/285 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- ADGRB2 | c.4469A>T p.Q1490L (on ENST00000373658 / NM_001364857.2; = p.Q1489L on NM_001294335.2) | Missense Mutation (SNP) | VAF 41/673 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.416); called by muse, mutect2
- ADGRB3 | c.2070G>T p.M690I | Missense Mutation (SNP) | VAF 8/247 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2
- ADH1A | c.264T>G p.D88E | Missense Mutation (SNP) | VAF 27/447 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2
- ALDH8A1 | c.1313T>C p.L438P | Missense Mutation (SNP) | VAF 39/704 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- APBB1 | c.1249G>T p.G417W | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGAP29 | c.1577G>T p.G526V | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2
- ARHGEF10L | c.326G>T p.W109L | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATIC | c.641A>G p.Q214R | Missense Mutation (SNP) | VAF 28/475 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP2C2 | c.2080_2083del p.T694Gfs*11 | Frame Shift Del (DEL) | VAF 28/189 reads (15%) | called by mutect2, pindel, varscan2
- AZIN2 | c.1108G>T p.G370C | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.873); called by muse, mutect2
- B3GNT3 | c.815G>C p.G272A | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BMP2 | c.1125C>G p.D375E | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- BPNT2 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 38/910 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C10orf82 | c.275-1G>A p.X92_splice | Splice Site (SNP) | VAF 10/155 reads (6%) | called by muse, mutect2
- C20orf194 | c.2801A>T p.E934V | Missense Mutation (SNP) | VAF 24/428 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.369); called by muse, mutect2
- C4orf54 | c.5005C>A p.P1669T | Missense Mutation (SNP) | VAF 25/257 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2
- CARNMT1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 52/416 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, varscan2
- CCDC136 | c.2674A>C p.K892Q | Missense Mutation (SNP) | VAF 42/830 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.045); called by muse, mutect2
- CD8A | c.692C>A p.S231* | Nonsense Mutation (SNP) | VAF 56/1052 reads (5%) | called by muse, mutect2
- CDYL2 | c.740G>T p.C247F | Missense Mutation (SNP) | VAF 44/466 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.053); called by muse, mutect2
- CENPF | c.5993G>C p.C1998S | Missense Mutation (SNP) | VAF 35/528 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- CEP41 | c.208-3C>G | Splice Region (SNP) | VAF 23/889 reads (3%) | called by muse, mutect2
- CEP68 | c.1769G>C p.R590P | Missense Mutation (SNP) | VAF 48/647 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.01); called by muse, mutect2
- CFAP100 | c.191T>G p.L64W | Missense Mutation (SNP) | VAF 53/571 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHD1 | c.1657G>T p.A553S | Missense Mutation (SNP) | VAF 32/666 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2
- CHD8 | c.3703_3704del p.N1235* (on ENST00000646647 / NM_001170629.2; = p.N956* on NM_020920.4) | Frame Shift Del (DEL) | VAF 15/147 reads (10%) | called by mutect2, pindel, varscan2
- CLCNKA | c.1150C>A p.P384T | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- CNTNAP5 | c.3726G>T p.G1242= | Splice Region (SNP) | VAF 8/113 reads (7%) | called by muse, mutect2
- CPNE8 | c.1291G>T p.D431Y | Missense Mutation (SNP) | VAF 38/376 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- CRISP2 | c.183+1G>A p.X61_splice | Splice Site (SNP) | VAF 40/793 reads (5%) | called by muse, mutect2
- CUBN | c.3692G>T p.S1231I | Missense Mutation (SNP) | VAF 39/813 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.261); called by muse, mutect2
- DDX11 | c.449G>T p.R150M | Missense Mutation (SNP) | VAF 87/845 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- DDX58 | c.2663A>C p.K888T | Missense Mutation (SNP) | VAF 61/624 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DENND2B | c.2453G>T p.R818L | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- DHX16 | c.992A>T p.E331V | Missense Mutation (SNP) | VAF 41/578 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.339); called by muse, mutect2
- DMD | c.1618T>A p.W540R | Missense Mutation (SNP) | VAF 33/356 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNA2 | c.959T>A p.L320Q | Missense Mutation (SNP) | VAF 33/492 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- DNAH9 | c.9948C>A p.N3316K | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- DNER | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DOCK4 | c.1029G>C p.K343N | Missense Mutation (SNP) | VAF 35/472 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- DOCK6 | c.3158A>G p.H1053R | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- DSE | c.831G>T p.Q277H | Missense Mutation (SNP) | VAF 34/732 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2
- EDARADD | c.239C>T p.P80L (on ENST00000334232 / NM_145861.4; = p.P70L on NM_080738.4) | Missense Mutation (SNP) | VAF 26/712 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- EDRF1 | c.930G>C p.W310C (on ENST00000356792 / NM_001202438.2; = p.W276C on NM_015608.2) | Missense Mutation (SNP) | VAF 40/864 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EFHB | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 14/415 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- EMILIN2 | c.109C>G p.P37A | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2
- EPHB6 | c.2525C>T p.S842F | Missense Mutation (SNP) | VAF 48/840 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- EVX1 | c.421A>T p.S141C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAM135B | c.3527C>G p.S1176C | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM135B | c.678C>A p.F226L | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); called by muse, mutect2
- FAT1 | c.10289T>C p.V3430A | Missense Mutation (SNP) | VAF 30/620 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- FREM3 | c.5593C>A p.L1865I | Missense Mutation (SNP) | VAF 31/416 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- FSIP2 | c.18937C>G p.L6313V | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- GIGYF2 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 46/894 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); called by muse, mutect2
- GPR15 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); called by muse, mutect2
- GPR63 | c.890A>C p.Q297P | Missense Mutation (SNP) | VAF 34/387 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.223); called by muse, mutect2
- GTSF1L | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 17/362 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- HNF4A | c.839A>G p.Q280R | Missense Mutation (SNP) | VAF 40/716 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.072); called by muse, mutect2
- IGKV3D-15 | c.190C>G p.P64A | Missense Mutation (SNP) | VAF 60/709 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IQSEC3 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 37/770 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.301); called by muse, mutect2
- ITGA2 | c.1135T>G p.S379A | Missense Mutation (SNP) | VAF 32/754 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.094); called by muse, mutect2
- ITPR1 | c.4947T>A p.S1649R (on ENST00000354582; = p.S1634R on NM_002222.7) | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- JAK1 | c.229C>T p.L77F | Missense Mutation (SNP) | VAF 27/536 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- KAZN | c.1576C>G p.H526D | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.955); called by muse, mutect2
- KCNK3 | c.872C>A p.A291E | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2
- KIF12 | c.534dup p.S179Vfs*95 (on ENST00000640217; = p.S41Vfs*95 on NM_138424.1) | Frame Shift Ins (INS) | VAF 8/70 reads (11%) | called by mutect2, pindel
- KIF20B | c.1346A>G p.K449R | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2
- KIF26B | c.1167-1G>T p.X389_splice | Splice Site (SNP) | VAF 21/292 reads (7%) | called by muse, mutect2
- KIF2A | c.1787G>C p.C596S | Missense Mutation (SNP) | VAF 11/265 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.015); called by muse, mutect2
- KIR3DL2 | c.674C>A p.S225Y | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMP5 | c.750G>T p.M250I | Missense Mutation (SNP) | VAF 25/497 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- LCE3A | c.223C>A p.Q75K | Missense Mutation (SNP) | VAF 25/374 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.99); called by muse, mutect2
- LILRA4 | c.923C>A p.P308H | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LINGO1 | c.1127G>T p.R376L | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- LRP1 | c.9238G>A p.G3080S | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- LRP12 | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- LRP8 | c.581A>T p.D194V | Missense Mutation (SNP) | VAF 31/485 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- LRRC36 | c.1162T>G p.S388A | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MAN1A1 | c.224A>T p.H75L | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.156); called by muse, mutect2
- MAST4 | c.3443G>T p.G1148V (on ENST00000403625 / NM_001164664.2; = p.G959V on NM_015183.3) | Missense Mutation (SNP) | VAF 41/726 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MEGF6 | c.3082T>C p.S1028P | Missense Mutation (SNP) | VAF 21/436 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.184); called by muse, mutect2
- MEX3A | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- MYCBP2 | c.5650G>T p.D1884Y (on ENST00000357337; = p.D1922Y on NM_015057.5) | Missense Mutation (SNP) | VAF 32/461 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- MYH13 | c.4099A>G p.K1367E | Missense Mutation (SNP) | VAF 37/629 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2
- NBPF4 | c.1535G>T p.S512I | Missense Mutation (SNP) | VAF 56/1367 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2
- NCOA3 | c.3067G>T p.G1023C | Missense Mutation (SNP) | VAF 45/575 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.103); called by muse, mutect2
- NCOA3 | c.3068G>T p.G1023V | Missense Mutation (SNP) | VAF 45/561 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.066); called by muse, mutect2
- NLRP1 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 39/679 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.066); called by muse, mutect2
- NPAS3 | c.326A>T p.Q109L (on ENST00000356141 / NM_001164749.2; = p.Q79L on NM_022123.3) | Missense Mutation (SNP) | VAF 20/554 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.021); called by muse, mutect2
- NPIPB15 | c.55C>A p.Q19K | Missense Mutation (SNP) | VAF 69/2013 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.136); called by muse, mutect2
- NUTM2F | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- OR11H7 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- OR51I2 | c.257G>A p.C86Y | Missense Mutation (SNP) | VAF 15/250 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- OR7G2 | c.36C>G p.I12M | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.366); called by muse, mutect2
- PCDH11X | c.1772T>A p.L591Q | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PHB | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 36/658 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2
- PLEKHH1 | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 30/373 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2
- POLR2B | c.940C>G p.Q314E | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.044); called by muse, mutect2
- POTEC | c.1092G>C p.Q364H | Missense Mutation (SNP) | VAF 21/586 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- PPP4R3C | c.1777G>T p.G593* | Nonsense Mutation (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- PRDM9 | c.703C>G p.P235A | Missense Mutation (SNP) | VAF 46/1030 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.021); called by muse, mutect2
- PREP | c.1723G>C p.D575H (on ENST00000369110; = p.D641H on NM_002726.5) | Missense Mutation (SNP) | VAF 36/466 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRKCB | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 19/337 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.035); called by muse, mutect2
- PROC | c.1140G>A p.M380I | Missense Mutation (SNP) | VAF 31/463 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- PRRC2C | c.7828C>G p.Q2610E (on ENST00000367742; = p.Q2608E on NM_015172.4) | Missense Mutation (SNP) | VAF 30/770 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- PSMA6 | c.553A>G p.K185E | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.059); called by muse, mutect2
- PSMB11 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RCOR3 | c.638C>G p.S213C | Missense Mutation (SNP) | VAF 34/812 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); called by muse, mutect2
- RIMS2 | c.3263C>G p.S1088C (on ENST00000666250 / NM_001348490.2; = p.S896C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/744 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- RPL11 | c.44G>C p.R15P (on ENST00000374550 / NM_001199802.1; = p.R16P on NM_000975.5) | Missense Mutation (SNP) | VAF 30/521 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.057); called by muse, mutect2
- RUBCNL | c.523G>C p.A175P | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- SEMA3A | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 40/570 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- SETBP1 | c.3039G>T p.L1013F | Missense Mutation (SNP) | VAF 42/730 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.332); called by muse, mutect2
- SFMBT2 | c.2639A>G p.Q880R | Missense Mutation (SNP) | VAF 25/350 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.171); called by muse, mutect2
- SH2B2 | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 22/442 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC12A5 | c.1291T>C p.F431L (on ENST00000454036 / NM_001134771.2; = p.F408L on NM_020708.5) | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- SLC12A7 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 69/434 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC36A4 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC8A1 | c.697T>C p.W233R | Missense Mutation (SNP) | VAF 15/314 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- SPATA31D1 | c.4263T>A p.H1421Q | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2
- SPTBN5 | c.551T>A p.L184Q | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SULF2 | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 37/504 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SYT16 | c.1203G>T p.R401S | Missense Mutation (SNP) | VAF 56/788 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- TAF3 | c.2645G>T p.G882V | Missense Mutation (SNP) | VAF 31/490 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TARBP1 | c.2916G>A p.M972I | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- TFPI | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 15/368 reads (4%) | called by muse, mutect2
- TIE1 | c.2945C>A p.A982D | Missense Mutation (SNP) | VAF 26/425 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMPRSS15 | c.590G>A p.C197Y | Missense Mutation (SNP) | VAF 20/507 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNS1 | c.2372G>T p.R791M | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); called by muse, mutect2
- TOPAZ1 | c.471G>T p.L157F | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.11); called by muse, mutect2
- TRAPPC9 | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 34/503 reads (7%) | called by muse, mutect2
- TRAV13-2 | c.37C>A p.L13M | Missense Mutation (SNP) | VAF 21/565 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRAV21 | c.251C>A p.S84* | Nonsense Mutation (SNP) | VAF 26/467 reads (6%) | called by muse, mutect2
- TRIM51GP | c.1189C>G p.L397V | Missense Mutation (SNP) | VAF 56/892 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.423); called by muse, mutect2
- TRPM6 | c.5642G>C p.G1881A | Missense Mutation (SNP) | VAF 111/1063 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBE2O | c.2269G>C p.E757Q | Missense Mutation (SNP) | VAF 5/134 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.133); called by muse, mutect2
- UNC13C | c.136A>C p.T46P | Missense Mutation (SNP) | VAF 20/524 reads (4%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2
- USP14 | c.1151A>G p.Q384R | Missense Mutation (SNP) | VAF 27/312 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.009); called by muse, mutect2
- USP36 | c.1798G>C p.D600H | Missense Mutation (SNP) | VAF 52/496 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- VAC14 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 33/336 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- VPS45 | c.1829A>G p.H610R (on ENST00000644526; = p.H505R on NM_001279353.2) | Missense Mutation (SNP) | VAF 21/373 reads (6%) | SIFT tolerated, low confidence (0.23); called by muse, mutect2
- WNK4 | c.3241G>C p.G1081R | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.109); called by muse, mutect2
- WNK4 | c.3507G>C p.K1169N | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- ZDHHC4 | c.574A>T p.R192W | Missense Mutation (SNP) | VAF 38/716 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZFPM2 | c.501C>A p.D167E | Missense Mutation (SNP) | VAF 50/670 reads (7%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.967); called by muse, mutect2
- ZNF185 | c.1919C>T p.P640L | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF451 | c.3070+7A>G | Splice Region (SNP) | VAF 27/391 reads (7%) | called by muse, mutect2
- ZNF599 | c.916A>T p.T306S | Missense Mutation (SNP) | VAF 83/621 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABL2 | c.2469A>G p.E823= (on ENST00000502732 / NM_007314.4; = p.E808= on NM_005158.5) | Silent (SNP) | VAF 24/566 reads (4%) | called by muse, mutect2
- ACAT2 | c.279G>T p.G93= | Silent (SNP) | VAF 30/764 reads (4%) | called by muse, mutect2
- APBB1IP | c.213G>T p.L71= | Silent (SNP) | VAF 15/236 reads (6%) | called by muse, mutect2
- APEH | c.900G>T p.L300= | Silent (SNP) | VAF 28/420 reads (7%) | called by muse, mutect2
- ARHGAP20 | c.897C>T p.L299= | Silent (SNP) | VAF 23/524 reads (4%) | catalogued as COSV52811756; called by muse, mutect2
- ARRDC3 | c.1077G>A p.R359= | Silent (SNP) | VAF 24/523 reads (5%) | catalogued as rs1052296873, COSV54366374; called by muse, mutect2
- BIRC2 | c.771G>A p.L257= | Silent (SNP) | VAF 20/284 reads (7%) | called by muse, mutect2
- C20orf144 | c.273G>A p.P91= | Silent (SNP) | VAF 30/426 reads (7%) | catalogued as rs754114109, COSV55778600; called by muse, mutect2
- C2CD4C | c.759C>T p.L253= | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- CCDC86 | c.69C>T p.T23= | Silent (SNP) | VAF 19/256 reads (7%) | called by muse, mutect2
- CCND1 | c.30G>T p.V10= | Silent (SNP) | VAF 27/396 reads (7%) | called by muse, mutect2
- CDON | c.1719C>T p.G573= | Silent (SNP) | VAF 64/852 reads (8%) | catalogued as rs983884085; called by muse, mutect2
- CENPA | c.408G>A p.E136= | Silent (SNP) | VAF 15/245 reads (6%) | called by muse, mutect2
- COL9A3 | c.1014C>A p.L338= | Silent (SNP) | VAF 20/302 reads (7%) | called by muse, mutect2
- COX11 | c.195T>C p.H65= | Silent (SNP) | VAF 46/688 reads (7%) | called by muse, mutect2
- DENND2B | c.2454G>T p.R818= | Silent (SNP) | VAF 11/125 reads (9%) | called by muse, mutect2
- DISP3 | c.3957C>A p.G1319= | Silent (SNP) | VAF 27/444 reads (6%) | called by muse, mutect2
- FAM71B | c.1143G>T p.T381= | Silent (SNP) | VAF 16/190 reads (8%) | catalogued as COSV57230725; called by muse, mutect2
- FASN | c.6684C>T p.G2228= | Silent (SNP) | VAF 65/592 reads (11%) | catalogued as rs199844292; called by muse, mutect2, varscan2
- GDF3 | c.477C>A p.T159= | Silent (SNP) | VAF 15/107 reads (14%) | called by muse, mutect2, varscan2
- GNAS | c.1966C>A p.R656= | Silent (SNP) | VAF 16/366 reads (4%) | called by muse, mutect2
- GPR42 | c.1026C>G p.A342= | Silent (SNP) | VAF 63/393 reads (16%) | called by muse, mutect2, varscan2
- GRK4 | c.321T>C p.D107= (on ENST00000398052 / NM_182982.3; = p.D75= on NM_005307.3) | Silent (SNP) | VAF 40/376 reads (11%) | catalogued as rs201617968; called by muse, mutect2, varscan2
- GRM6 | c.1861C>A p.R621= | Silent (SNP) | VAF 36/380 reads (9%) | catalogued as CM050642, COSV99179689; called by muse, mutect2
- GRM8 | c.1884G>C p.G628= | Silent (SNP) | VAF 24/456 reads (5%) | catalogued as COSV58841588; called by muse, mutect2
- GUCY1A2 | c.2181C>A p.L727= | Silent (SNP) | VAF 44/394 reads (11%) | catalogued as COSV56496468, COSV56502335; called by muse, mutect2, varscan2
- INO80 | c.1359G>A p.K453= | Silent (SNP) | VAF 18/514 reads (4%) | called by muse, mutect2
- ITGA10 | c.1335C>A p.R445= | Silent (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- KCNA5 | c.1785C>T p.D595= | Silent (SNP) | VAF 42/820 reads (5%) | called by muse, mutect2
- KMO | c.816C>G p.L272= | Silent (SNP) | VAF 24/489 reads (5%) | catalogued as COSV100844724; called by muse, mutect2
- KRT74 | c.300G>T p.G100= | Silent (SNP) | VAF 29/494 reads (6%) | called by muse, mutect2
- KRT75 | c.393G>T p.L131= | Silent (SNP) | VAF 24/464 reads (5%) | catalogued as COSV99359630; called by muse, mutect2
- KRTAP13-2 | c.249C>A p.P83= | Silent (SNP) | VAF 14/224 reads (6%) | catalogued as COSV67762147, COSV67762369; called by muse, mutect2
- MAST4 | c.3444G>T p.G1148= (on ENST00000403625 / NM_001164664.2; = p.G959= on NM_015183.3) | Silent (SNP) | VAF 41/721 reads (6%) | called by muse, mutect2
- MROH9 | c.1692G>T p.L564= | Silent (SNP) | VAF 10/234 reads (4%) | called by muse, mutect2
- MUC16 | c.3759C>A p.L1253= | Silent (SNP) | VAF 18/242 reads (7%) | catalogued as COSV67469253; called by muse, mutect2
- MXRA5 | c.8019C>A p.L2673= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV54238387; called by muse, mutect2, varscan2
- NELL1 | c.913C>A p.R305= | Silent (SNP) | VAF 68/1087 reads (6%) | catalogued as COSV100126029; called by muse, mutect2
- OR10V1 | c.744G>T p.V248= | Silent (SNP) | VAF 13/197 reads (7%) | called by muse, mutect2
- PCDHB14 | c.2043C>A p.A681= | Silent (SNP) | VAF 42/646 reads (7%) | catalogued as COSV53388397; called by muse, mutect2
- PENK | c.726C>T p.P242= | Silent (SNP) | VAF 18/246 reads (7%) | catalogued as COSV59240006; called by muse, mutect2
- POU6F2 | c.1419G>T p.A473= | Silent (SNP) | VAF 38/591 reads (6%) | catalogued as COSV68873665; called by muse, mutect2
- PPM1E | c.1308C>A p.G436= | Silent (SNP) | VAF 28/412 reads (7%) | called by muse, mutect2
- PRIMA1 | c.189G>T p.P63= | Silent (SNP) | VAF 5/87 reads (6%) | catalogued as rs775188425; called by muse, mutect2
- PRPH | c.457C>A p.R153= | Silent (SNP) | VAF 15/251 reads (6%) | called by muse, mutect2
- S1PR1 | c.1134C>T p.V378= | Silent (SNP) | VAF 18/358 reads (5%) | called by muse, mutect2
- SLC15A4 | c.285G>T p.L95= | Silent (SNP) | VAF 17/248 reads (7%) | called by muse, mutect2
- SLIT2 | c.2058G>A p.T686= | Silent (SNP) | VAF 28/556 reads (5%) | catalogued as rs753942846; called by muse, mutect2
- SOAT2 | c.948C>A p.G316= | Silent (SNP) | VAF 26/358 reads (7%) | catalogued as rs145673543; called by muse, mutect2
- TENM4 | c.7707G>T p.G2569= | Silent (SNP) | VAF 50/620 reads (8%) | catalogued as COSV53673282; called by muse, mutect2
- TEX14 | c.2550A>T p.G850= (on ENST00000240361 / NM_001201457.2; = p.G844= on NM_031272.5) | Silent (SNP) | VAF 31/494 reads (6%) | called by muse, mutect2
- TGIF2LX | c.321C>A p.R107= | Silent (SNP) | VAF 52/649 reads (8%) | catalogued as rs765216141; called by muse, mutect2
- TIGD3 | c.1029G>T p.V343= | Silent (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- TMEM178B | c.609G>T p.V203= | Silent (SNP) | VAF 28/438 reads (6%) | catalogued as rs1407925306; called by muse, mutect2
- TNFAIP2 | c.1839C>T p.S613= | Silent (SNP) | VAF 32/512 reads (6%) | catalogued as rs200790378, COSV100280891; called by muse, mutect2
- TNN | c.315C>A p.V105= | Silent (SNP) | VAF 22/426 reads (5%) | catalogued as COSV53421357; called by muse, mutect2
- TOMM40L | c.333C>G p.V111= | Silent (SNP) | VAF 24/441 reads (5%) | called by muse, mutect2
- TOX2 | c.1146C>G p.P382= (on ENST00000358131 / NM_001098798.2; = p.P358= on NM_032883.3) | Silent (SNP) | VAF 12/135 reads (9%) | called by muse, mutect2
- TTC37 | c.1293C>T p.F431= | Silent (SNP) | VAF 22/518 reads (4%) | called by muse, mutect2
- UBN1 | c.645G>T p.S215= | Silent (SNP) | VAF 23/410 reads (6%) | catalogued as COSV99277824; called by muse, mutect2
- UNC80 | c.57C>G p.P19= | Silent (SNP) | VAF 24/594 reads (4%) | called by muse, mutect2
- YOD1 | c.778C>T p.L260= | Silent (SNP) | VAF 36/593 reads (6%) | catalogued as COSV100263299, COSV60006185; called by muse, mutect2
- ZSCAN1 | c.609C>A p.S203= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV56605607, COSV56606144, COSV56607804; called by muse, mutect2, varscan2
- AC243965.1 | n.375C>A | RNA (SNP) | VAF 30/489 reads (6%) | called by muse, mutect2
- AOAH | c.128-3346G>A | Intron (SNP) | VAF 14/276 reads (5%) | called by muse, mutect2
- ATP6AP2 | c.301-17T>C | Intron (SNP) | VAF 26/232 reads (11%) | called by muse, mutect2, varscan2
- C1orf87 | c.-1C>T | 5'UTR (SNP) | VAF 19/279 reads (7%) | called by muse, mutect2
- CCDC38 | c.38-631G>T | Intron (SNP) | VAF 25/407 reads (6%) | called by muse, mutect2
- CTNND2 | c.2638-1035G>T | Intron (SNP) | VAF 16/120 reads (13%) | called by muse, varscan2
- CYLC1 | c.-23C>G | 5'UTR (SNP) | VAF 24/197 reads (12%) | called by muse, mutect2, varscan2
- DMAP1 | c.393+226C>T | Intron (SNP) | VAF 28/350 reads (8%) | catalogued as rs758715668; called by muse, mutect2
- DPY19L2 | c.1580+3021G>C | Intron (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2, varscan2
- EVI5 | c.1344+3098G>T | Intron (SNP) | VAF 19/301 reads (6%) | called by muse, mutect2
- FBXW5 | c.527-13G>T | Intron (SNP) | VAF 28/166 reads (17%) | catalogued as rs368747499; called by muse, mutect2, varscan2
- FRG2KP | chr16:31569297 C>A | 5'Flank (SNP) | VAF 22/376 reads (6%) | catalogued as rs756131655; called by muse, mutect2
- GCNT2 | c.925+27069G>T | Intron (SNP) | VAF 15/256 reads (6%) | called by muse, mutect2
- GUCY1B2 | n.822A>T | RNA (SNP) | VAF 28/553 reads (5%) | called by muse, mutect2
- HBE1 | c.-267+102301G>T | Intron (SNP) | VAF 23/442 reads (5%) | called by muse, mutect2
- HBE1 | c.-267+74745G>T | Intron (SNP) | VAF 37/838 reads (4%) | called by muse, mutect2
- HDC | c.*34C>A | 3'UTR (SNP) | VAF 20/281 reads (7%) | called by muse, mutect2
- HNRNPLL | c.-282G>T | 5'UTR (SNP) | VAF 24/374 reads (6%) | called by muse, mutect2
- IGFN1 | c.1241+2015G>T | Intron (SNP) | VAF 21/422 reads (5%) | catalogued as COSV55180238; called by muse, mutect2
- IGFN1 | c.1242-593G>T | Intron (SNP) | VAF 25/252 reads (10%) | catalogued as rs1319090144, COSV55171064; called by muse, mutect2, varscan2
- LAIR2 | c.*3G>A | 3'UTR (SNP) | VAF 46/470 reads (10%) | catalogued as rs1472211111, COSV100003302; called by muse, mutect2
- LAPTM4B | c.-125C>A | 5'UTR (SNP) | VAF 32/746 reads (4%) | called by muse, mutect2
- MARF1 | chr16:15643271 G>A | 5'Flank (SNP) | VAF 11/71 reads (15%) | called by muse, mutect2, varscan2
- ME3 | c.920-7275G>C | Intron (SNP) | VAF 14/312 reads (4%) | called by muse, mutect2
- MGAM | c.4619-2617C>T | Intron (SNP) | VAF 8/291 reads (3%) | called by muse, mutect2
- OSR2 | c.-90C>A | 5'UTR (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- RFX7 | c.-215C>T | 5'UTR (SNP) | VAF 24/282 reads (9%) | called by muse, mutect2
- RPE65 | c.*9C>A | 3'UTR (SNP) | VAF 29/641 reads (5%) | called by muse, mutect2
- SERPINA3 | c.917+27C>G | Intron (SNP) | VAF 36/513 reads (7%) | called by muse, mutect2
- SLMAP | c.-2C>T | 5'UTR (SNP) | VAF 34/384 reads (9%) | called by muse, mutect2
- STAU2 | c.1530+24223A>T | Intron (SNP) | VAF 23/309 reads (7%) | called by muse, mutect2
- TAL1 | c.*189G>A | 3'UTR (SNP) | VAF 40/840 reads (5%) | catalogued as rs1345062680; called by muse, mutect2
- TMPRSS3 | c.*64G>T | 3'UTR (SNP) | VAF 32/504 reads (6%) | called by muse, mutect2
- TRDV2 | chr14:22418351 G>A | 5'Flank (SNP) | VAF 7/136 reads (5%) | catalogued as rs1434733732; called by muse, mutect2
- TXNRD3 | n.758G>A | RNA (SNP) | VAF 14/212 reads (7%) | called by muse, mutect2
- UGGT2 | c.-12T>C | 5'UTR (SNP) | VAF 20/314 reads (6%) | called by muse, mutect2
- ZFAND2B | c.*31G>A | 3'UTR (SNP) | VAF 34/402 reads (8%) | catalogued as COSV99202419; called by muse, mutect2
- ZNF280D | c.1854-31A>G | Intron (SNP) | VAF 20/222 reads (9%) | catalogued as rs1159387237; called by muse, mutect2
